Somatic mutation profile of tumor specimen TARGET-10-PARWMF-09A (aliquot TARGET-10-PARWMF-09A-01D) from TARGET case TARGET-10-PARWMF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.7 years (4,275 days).
Specimen TARGET-10-PARWMF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c30e93eb-8b2b-4c16-9918-e55ae4c1a1a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARWMF-10A (Blood Derived Normal), aliquot TARGET-10-PARWMF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a35a5dd1-bffa-422e-abb2-5a669cf51f2b

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 4, Silent 3, Intron 3, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 32/206 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 36/122 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, varscan2
- WT1 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 47/149 reads (32%) | catalogued as rs121907906, CM930742, COSV60068301; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBOF1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67454640; called by muse, mutect2, varscan2
- C8B | c.1502G>C p.S501T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV64776871; called by muse, mutect2, varscan2
- COL5A2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs754702218, COSV66408204; called by muse, mutect2, varscan2
- EIF4G3 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539091547, COSV51674560; called by muse, mutect2, varscan2
- FBXW7 | c.1856-2A>G p.X619_splice (on ENST00000281708 / NM_001349798.2; = p.X539_splice on NM_018315.5) | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as COSV55903044; called by muse, mutect2, varscan2
- GRHL2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1450530282, COSV52546264; called by muse, mutect2, varscan2
- HOXA1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562699067, COSV58029290; called by muse, mutect2
- KALRN | c.5032C>T p.R1678W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368179672; called by muse, mutect2, varscan2
- KIF20B | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV53301744; called by muse, mutect2, varscan2
- NAV2 | c.980C>T p.P327L (on ENST00000396087 / NM_001244963.2; = p.P304L on NM_145117.5) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as rs202102258, COSV62318377; called by muse, mutect2, varscan2
- NF1 | c.5546A>T p.D1849V (on ENST00000358273 / NM_001042492.3; = p.D1828V on NM_000267.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62197026; called by muse, mutect2, varscan2
- PTPRG | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as rs749195922, COSV55633524; called by muse, mutect2, varscan2
- RIMS2 | c.4496C>T p.T1499M (on ENST00000666250 / NM_001348490.2; = p.T1070M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751410503, COSV51658657; called by muse, mutect2, varscan2
- SNX29 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs754710479, COSV73829694; called by muse, mutect2, varscan2
- SUZ12 | c.823+1G>C p.X275_splice | Splice Site (SNP) | VAF 38/86 reads (44%) | catalogued as COSV59498780, COSV59501039; called by muse, mutect2, varscan2
- TBC1D30 | c.2632G>A p.V878I (on ENST00000542120; = p.V715I on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.403); catalogued as rs766614364, COSV57480979; called by muse, mutect2, varscan2
- TNXB | c.8630G>A p.R2877H (on ENST00000647633; = p.R2630H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs374865424; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXW7 | c.1386dup p.T463Hfs*9 (on ENST00000281708 / NM_001349798.2; = p.T383Hfs*9 on NM_018315.5) | Frame Shift Ins (INS) | VAF 12/134 reads (9%) | called by pindel, varscan2
- PHF6 | c.861del p.A288Lfs*7 | Frame Shift Del (DEL) | VAF 18/21 reads (86%) | called by mutect2, pindel*, varscan2
- CSMD2 | c.8172C>T p.N2724= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs140959425, COSV53917896; called by muse, mutect2
- KEL | c.783G>A p.L261= | Silent (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- PDE11A | c.2740C>T p.L914= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- ADCK5 | c.342+27G>A | Intron (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- AP4M1 | c.*331T>C | 3'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs759333845; called by muse, varscan2
- ATP6V0E1 | chr5:173020837 G>A | 3'Flank (SNP) | VAF 23/95 reads (24%) | catalogued as rs778165480; called by muse, mutect2, varscan2
- LGI2 | c.*3676G>A | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- NUDT3 | c.*131G>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2
- PRDM5 | c.-39C>T | 5'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- PXDN | c.*9G>A | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- RNF213 | c.11055-138_11055-137insTG | Intron (INS) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- TYK2 | c.2908+30T>C | Intron (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
